Somatic mutation profile of tumor specimen TARGET-10-PANYZE-09A (aliquot TARGET-10-PANYZE-09A-01D) from TARGET case TARGET-10-PANYZE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,479 days).
Specimen TARGET-10-PANYZE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bda0f67-f98b-4fc1-850d-525e65cd90ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANYZE-14A (Bone Marrow Normal), aliquot TARGET-10-PANYZE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5bd7291-7135-41b1-8bfc-d7a7c0e26221

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, RNA 2, Silent 1, Intron 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C21orf91 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53032847; called by muse, mutect2, varscan2
- CD8B2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs976215620; called by muse, mutect2
- NPAS3 | c.586G>A p.D196N (on ENST00000356141 / NM_001164749.2; = p.D164N on NM_022123.3) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1187772913, COSV58119987; called by muse, mutect2, varscan2
- PLEKHH1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs555885454, COSV61286381; called by muse, mutect2, varscan2
- SUPT6H | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV58927143; called by muse, mutect2
- CREBBP | c.3185_3189del p.E1062Gfs*3 | Frame Shift Del (DEL) | VAF 78/193 reads (40%) | called by mutect2, pindel, varscan2
- FAM135B | c.1510dup p.I504Nfs*3 | Frame Shift Ins (INS) | VAF 65/162 reads (40%) | called by mutect2, pindel, varscan2
- FLG2 | c.6007G>T p.D2003Y | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HERC2 | c.10043G>T p.G3348V | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- PKHD1 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC6A5 | c.985+1G>C p.X329_splice | Splice Site (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- CLCA4 | c.2346T>C p.D782= | Silent (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- EYA1 | c.-54-171A>G | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- HSPA7 | n.970C>T | RNA (SNP) | VAF 54/105 reads (51%) | catalogued as rs748255020; called by muse, mutect2, varscan2
- RFPL3 | c.*139G>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as rs1267427274; called by muse, mutect2
- VENTXP1 | n.577G>A | RNA (SNP) | VAF 9/61 reads (15%) | catalogued as rs890195005; called by muse, mutect2, varscan2
